Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91K, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91K-01A (Primary Tumor).

Collect date:

ICD-0-3

Adenocarcinoma, intestinal
Type 8144/3

Site: Gastric antrum C16.3
4/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

I-) Duodenal margin.

-Uninvolved by neoplasia.

II-) Gallbladder.

-Chronic cholecystitis.

III-) Gastric wall nodule.

-Lymph node without atypia.

IV-) Product of gastrectomy.

-Moderately differentiated adenocarcinoma (intestinal type of Laurén), with 2.8 cm in the largest size.

-Tumor at pyloric region and duodenum.

-Tumor invades all width of gastric wall, and invades also perigastric fat and peritoneum.

-Moderate stromal desmoplasia.

-Moderate intratumoral lymphocytic infiltrate.

-Tumor lymphatic invasion.

-Venous and perineural invasion not observed.

-Proximal and distal margins uninvolved by neoplasia.

-Non-tumor gastric mucosa with moderate chronic gastritis and discrete activity.

-Areas of atrophic gastritis with discrete fibrosis in submucosa in the body.

V-) Spleen.

-Hyaline perisplenitis.

VI-) Omentum.

-Uninvolved by neoplasia.

VII-) Lymphadenectomy according to standardization:

Right paracardic.

-Uninvolved by neoplasia (0/6).

Lesser curvature.

-Metastatic adenocarcinoma (2/5), without capsular transposition.

Short gastric.

Primary Tumor Site: Intestine		
Primary Tumor Site: Stomach		
Primary Tumor Site: Esophagus		
Primary Tumor Site: Pancreas		
Primary Tumor Site: Liver		
Primary Tumor Site: Gallbladder		
Primary Tumor Site: Spleen		
Primary Tumor Site: Omentum		
Primary Tumor Site: Lymph Nodes		
Primary Tumor Site: Other		
Use is (circled)		
Reviewed Initials		

Source: NCI Genomic Data Commons file b3a4abb1-b2c9-4a98-b8d0-0555df88d11f (TCGA-VQ-A91K.99B38537-E32F-4EFE-9E8B-E1A84D02FA4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).